Somatic mutation profile of tumor specimen 0DXDVR from CCDI case PBCRGN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 0.9 years (342 days).
Specimen 0DXDVR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085f0f5f-5eb5-417e-87e7-d88c1f09ab86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXDV2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41dd1fce-e930-4a3c-9f5b-9940c4de65a5

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.305_306del p.C102Yfs*7 | Frame Shift Del (DEL) | VAF 150/339 reads (44%) | catalogued as rs587778825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IQSEC2 | c.1106G>A p.R369Q (on ENST00000642864 / NM_001111125.3; = p.R164Q on NM_015075.2) | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1556864710; called by muse, mutect2, varscan2
- RPS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 161/354 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs747317928, COSV53705278; called by muse, mutect2, varscan2
